Gene-level copy-number profile of tumor specimen TCGA-KK-A59Y-01A from TCGA case TCGA-KK-A59Y, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.9 years (20,768 days).
Specimen TCGA-KK-A59Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.8a4ef113-6cc5-4247-95cd-86ab2c647653.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A59Y-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9edcef14-e29d-4909-b053-9552ad68bdb3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 4; copy number 2: 5,614; copy number 3: 27; copy number 4: 51,445; copy number 5: 123; copy number 6: 2,574.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A59Y-01A-11D-A26L-01): tumor purity 0.77, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:55,978,248–56,233,330, 6 genes (within-gene range 0–2): AC008892.1, FLJ31104, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184.
- chr10:87,659,613–87,863,533, 5 genes: PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.
- chr10:87,878,692–87,880,427, 1 gene: AC063965.2.
- chr11:113,974,881–114,595,786, 17 genes: HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2, NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
